Somatic mutation profile of tumor specimen C3L-02890-01 (aliquot CPT0166650009) from CPTAC case C3L-02890, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.8 years (24,050 days).
Specimen C3L-02890-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9d9a236-6753-48e8-b826-afa40cda5cb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02890-31 (Blood Derived Normal), aliquot CPT0166690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1417e506-3e7a-427d-84d3-8b2c79fd848d

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 2, Intron 2, 5'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 238/1304 reads (18%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 91/729 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 54/908 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs756736504, COSV55944903; ClinVar: drug response; called by muse, mutect2
- AMPD1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 35/724 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs139512772; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1E | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs777265667, COSV100704395, COSV62399491; called by muse, mutect2
- CAMK1D | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs912179319, COSV66609732, COSV66615386; called by muse, mutect2
- CC2D2A | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs367699902, COSV67503463; called by muse, mutect2
- CCDC116 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs9609909; called by muse, mutect2
- CDK12 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 17/575 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217963220, COSV70999525; called by muse, mutect2
- CHST6 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778668750, CM032869, COSV60000196; called by muse, mutect2
- DCAF1 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV100244354, COSV60046479; called by muse, mutect2
- DOHH | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766745007; called by muse, mutect2
- GLDC | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 78/794 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs754581403; called by muse, mutect2
- GRM8 | c.2158dup p.H720Pfs*5 | Frame Shift Ins (INS) | VAF 17/129 reads (13%) | catalogued as rs772717214; called by mutect2, varscan2
- GYS2 | c.422del p.G141Afs*13 | Frame Shift Del (DEL) | VAF 59/561 reads (11%) | catalogued as COSV53920368; called by mutect2, pindel, varscan2
- HAO2 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58037676; called by muse, mutect2
- HNRNPK | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1194524404, COSV57935759; called by muse, mutect2
- IGSF1 | c.1619G>A p.R540K | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1283637501; called by muse, mutect2
- MED24 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs776181925; called by muse, mutect2
- NEFM | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 50/1476 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1243436231; called by muse, mutect2
- NPTX2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483768781; called by muse, mutect2, varscan2
- PAX4 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 57/614 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780414, COSV58392056; ClinVar: uncertain significance; called by muse, mutect2
- PCDHA9 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 30/736 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562459111, COSV65334072; called by muse, mutect2
- PCSK1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 46/423 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs368253923, COSV60735165; called by muse, mutect2, varscan2
- POGLUT2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 17/469 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV99959204; called by muse, mutect2
- PRR14L | c.4220G>A p.R1407H | Missense Mutation (SNP) | VAF 58/736 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773119037, COSV57883076; called by muse, mutect2
- PRUNE2 | c.3184G>T p.G1062C | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV65041970; called by muse, mutect2
- RFX5 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 63/650 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs138131380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2B3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 34/936 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs776655476, COSV57983479; called by muse, mutect2
- SOGA3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV100846857; called by muse, mutect2
- UNCX | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100310246; called by muse, mutect2
- WNT9A | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 28/864 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV55297172; called by muse, mutect2
- ZNF521 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 151/498 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs770755347, COSV64124244, COSV64127046; called by muse, mutect2, varscan2
- ABHD3 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 49/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADGRB1 | c.691del p.R231Afs*6 | Frame Shift Del (DEL) | VAF 44/404 reads (11%) | called by mutect2, pindel, varscan2
- AJAP1 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP5 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ASPM | c.5635A>G p.I1879V | Missense Mutation (SNP) | VAF 48/523 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.157); called by muse, mutect2
- CACNA1G | c.5969T>G p.I1990S | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FNDC1 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- FZD10 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- INSRR | c.3713C>G p.S1238C | Missense Mutation (SNP) | VAF 47/779 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2
- IRX2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 64/739 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIRREL3 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2
- KLHL29 | c.2476A>G p.T826A | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2
- KLHL9 | c.1492A>G p.I498V | Missense Mutation (SNP) | VAF 81/1106 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.714); called by muse, mutect2
- PCDH11X | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB16 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 37/443 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2
- RESF1 | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SLC15A2 | c.947T>G p.L316W | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SLCO4A1 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SNTB1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SPDYE3 | c.1283C>A p.A428E | Missense Mutation (SNP) | VAF 78/1798 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- TFAP2E | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- TMEM147 | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 30/732 reads (4%) | called by muse, mutect2
- TULP4 | c.381+2T>G p.X127_splice | Splice Site (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- ZCWPW2 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.249); called by muse, mutect2
- ZNF717 | c.799A>C p.K267Q | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.193); called by muse, mutect2
- ADAM11 | c.2262G>A p.T754= | Silent (SNP) | VAF 30/397 reads (8%) | catalogued as rs575543165, COSV52344884; called by muse, mutect2
- ADGRB1 | c.687C>G p.A229= | Silent (SNP) | VAF 48/392 reads (12%) | called by mutect2, varscan2
- AMER3 | c.534G>A p.A178= | Silent (SNP) | VAF 26/339 reads (8%) | catalogued as rs375834725, COSV100366251; called by muse, mutect2
- FER1L5 | c.2574C>T p.G858= (on ENST00000623019; = p.G863= on NM_001293083.2) | Silent (SNP) | VAF 14/395 reads (4%) | catalogued as rs1483860824; called by muse, mutect2
- GPR25 | c.378C>T p.G126= | Silent (SNP) | VAF 35/580 reads (6%) | called by muse, mutect2
- GSTA1 | c.321C>T p.L107= | Silent (SNP) | VAF 31/505 reads (6%) | catalogued as rs1051720; called by muse, mutect2
- HLTF | c.489G>A p.Q163= | Silent (SNP) | VAF 22/365 reads (6%) | called by muse, mutect2
- IQCE | c.1974C>G p.P658= | Silent (SNP) | VAF 17/279 reads (6%) | called by muse, mutect2
- MAGEL2 | c.2646C>T p.S882= | Silent (SNP) | VAF 68/798 reads (9%) | catalogued as rs747679005, COSV58566556; called by muse, mutect2
- NES | c.717G>A p.R239= | Silent (SNP) | VAF 80/912 reads (9%) | catalogued as rs775804285; called by muse, mutect2
- OTOP2 | c.1104C>T p.D368= | Silent (SNP) | VAF 47/631 reads (7%) | catalogued as rs768778471, COSV58882465; called by muse, mutect2
- PXDNL | c.2991T>C p.V997= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- SALL1 | c.3327G>A p.P1109= | Silent (SNP) | VAF 28/643 reads (4%) | catalogued as rs375357921; called by muse, mutect2
- SLC9C1 | c.291G>A p.T97= | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as rs200555832; called by muse, mutect2
- ADORA1 | c.-166C>A | 5'UTR (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- HLA-V | chr6:29792098 G>T | 5'Flank (SNP) | VAF 24/784 reads (3%) | catalogued as rs774797738; called by muse, mutect2
- LRSAM1 | c.1260-44G>A | Intron (SNP) | VAF 21/338 reads (6%) | catalogued as rs375139081; called by muse, mutect2
- NDOR1 | c.-2C>T | 5'UTR (SNP) | VAF 106/981 reads (11%) | catalogued as rs752203472, COSV100641649; called by muse, mutect2, varscan2
- UNC13C | c.4933+1831C>T | Intron (SNP) | VAF 26/364 reads (7%) | catalogued as rs1034254135; called by muse, mutect2
